Somatic mutation profile of tumor specimen TCGA-ZF-AA5P-01A (aliquot TCGA-ZF-AA5P-01A-11D-A391-08) from TCGA case TCGA-ZF-AA5P, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Posterior wall of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 65.6 years (23,971 days).
Specimen TCGA-ZF-AA5P-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8eff1de1-519c-4a4e-944d-8f810730721e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZF-AA5P-10A (Blood Derived Normal), aliquot TCGA-ZF-AA5P-10A-01D-A394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e295588f-79ae-42d7-bc10-ec689d79c6fc

The open-access MAF lists 41 somatic variants for this specimen: 31 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 9, Frame Shift Del 1, Splice Site 1, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.578A>G p.H193R | Missense Mutation (SNP) | VAF 6/42 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786201838, CM083194, CM951225, COSV52662414, COSV52663304, COSV52681707; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ARL6 | c.536-1G>C p.X179_splice | Splice Site (SNP) | VAF 8/186 reads (4%) | catalogued as COSV60119136; called by muse, mutect2
- CCDC25 | c.334C>T p.H112Y | Missense Mutation (SNP) | VAF 8/115 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV62959780; called by muse, mutect2
- CD37 | c.87C>G p.I29M | Missense Mutation (SNP) | VAF 12/346 reads (3%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.891); catalogued as COSV60543406, COSV60545406; called by muse, mutect2
- CHD8 | c.4292G>T p.R1431L (on ENST00000646647 / NM_001170629.2; = p.R1152L on NM_020920.4) | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV63219340, COSV63219814; called by muse, varscan2
- CLIP1 | c.550C>G p.P184A | Missense Mutation (SNP) | VAF 8/194 reads (4%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV56808284, COSV56809690; called by muse, mutect2
- CRYBG2 | c.4398C>G p.S1466R | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV57490995; called by muse, mutect2
- DDX19A | c.544G>C p.E182Q | Missense Mutation (SNP) | VAF 9/141 reads (6%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.998); catalogued as COSV56361563; called by muse, mutect2
- ETV4 | c.604C>T p.R202W | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.828); catalogued as rs144213199; called by muse, mutect2, varscan2
- FCRL1 | c.572C>T p.P191L | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV63828014; called by muse, mutect2, varscan2
- FMO2 | c.411T>A p.S137R | Missense Mutation (SNP) | VAF 4/102 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.011); catalogued as COSV99269021; called by muse, mutect2
- GLIS3 | c.432G>C p.K144N | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs753764072, COSV60937461; called by mutect2, varscan2
- HTATSF1 | c.967G>T p.E323* | Nonsense Mutation (SNP) | VAF 15/135 reads (11%) | catalogued as COSV99511501; called by mutect2, varscan2
- IGHG1 | c.413G>A p.R138Q | Missense Mutation (SNP) | VAF 20/137 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.029); catalogued as rs912746964; called by muse, mutect2, varscan2
- IGHG2 | c.539G>A p.R180H | Missense Mutation (SNP) | VAF 18/327 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.123); catalogued as rs202145150; called by muse, mutect2
- IGHV2-5 | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as rs782094050; called by muse, mutect2
- KCNJ4 | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.429); catalogued as rs762869037, COSV57859128; called by muse, mutect2, varscan2
- LZTR1 | c.344C>T p.P115L | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756852884, COSV53152431; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NCBP3 | c.1711G>A p.E571K | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.98); catalogued as COSV50112358; called by muse, mutect2
- NOL9 | c.553G>C p.E185Q | Missense Mutation (SNP) | VAF 9/154 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.852); catalogued as COSV100062914, COSV60230613; called by muse, mutect2
- PFAS | c.2477C>T p.S826L | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV58983973; called by muse, mutect2, varscan2
- PLPPR5 | c.362G>T p.R121L | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.894); catalogued as COSV99587127; called by muse, mutect2, varscan2
- PPARG | c.746C>T p.S249L (on ENST00000287820 / NM_015869.5; = p.S219L on NM_005037.7) | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as CM1412199, COSV55143511; called by muse, mutect2, varscan2
- RLF | c.2285A>G p.H762R | Missense Mutation (SNP) | VAF 9/123 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65653435; called by muse, mutect2
- SAGE1 | c.189G>C p.K63N | Missense Mutation (SNP) | VAF 7/120 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as COSV61018952; called by muse, mutect2
- SEMG1 | c.1148C>T p.A383V | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.563); catalogued as COSV99725157; called by muse, mutect2
- SOS2 | c.428A>C p.K143T | Missense Mutation (SNP) | VAF 11/164 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53566875, COSV53575882; called by muse, mutect2
- SPTA1 | c.3807G>T p.E1269D | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.074); catalogued as COSV63761068; called by muse, mutect2, varscan2
- TMEM200A | c.439C>G p.L147V | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51652702, COSV51660920; called by muse, mutect2
- UBE2Q1 | c.656del p.D219Vfs*12 | Frame Shift Del (DEL) | VAF 9/83 reads (11%) | catalogued as COSV52727328; called by mutect2, varscan2
- IGHV3-16 | c.19T>A p.W7R | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDK3 | c.648T>C p.F216= | Silent (SNP) | VAF 28/201 reads (14%) | catalogued as COSV56916953; called by muse, mutect2, varscan2
- CDX2 | c.487C>A p.R163= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as rs1437512268, COSV66829952; called by muse, mutect2, varscan2
- COL5A2 | c.3825C>A p.L1275= | Silent (SNP) | VAF 10/69 reads (14%) | catalogued as rs1328177067, COSV66411653, COSV66412002; called by muse, mutect2, varscan2
- FBXW12 | c.1245C>A p.L415= | Silent (SNP) | VAF 9/64 reads (14%) | catalogued as COSV56485850; called by muse, mutect2, varscan2
- NFATC2 | c.1977C>T p.Y659= | Silent (SNP) | VAF 21/206 reads (10%) | catalogued as rs142900177, COSV101043914; called by muse, mutect2, varscan2
- SLC1A5 | c.1368C>A p.I456= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as COSV69467527, COSV69467695; called by muse, mutect2, varscan2
- SLC1A5 | c.1212C>T p.L404= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as COSV69467702; called by muse, varscan2
- THAP3 | c.204A>C p.G68= | Silent (SNP) | VAF 4/54 reads (7%) | catalogued as COSV99275579; called by muse, mutect2
- TSG101 | c.1113C>T p.F371= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as COSV52653374; called by muse, mutect2
- MOCS1 | c.124-62C>T | Intron (SNP) | VAF 11/51 reads (22%) | catalogued as COSV57937027; called by muse, mutect2, varscan2
